Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6228, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6228-01A (Primary Tumor).

[page 1 of 7]
Specimen(s) Received

1. Soft-Tissue: [REDACTED] Lt inferior alveolus
2. Soft Tissue: Level 5B fat
3. Muscle: Deep paraspinal muscles [REDACTED]
4. Muscle: Anterior scalene muscle
5. Muscle: Deep scalene margin [REDACTED]
6. Muscle: Deep scalene margin 2 final resection [REDACTED]
7. Vessel: Carotid margin [REDACTED]
8. Soft Tissue: Rt. Level one
9. Oral Cavity: Lt. ventral tongue [REDACTED]
10. Oral Cavity: Rt. ventral tongue [REDACTED]
11. Oral Cavity: Rt. posterior floor of mouth [REDACTED]
12. Oral Cavity: Posterior floor of mouth [REDACTED]
13. Oral Cavity: Left deep tongue [REDACTED]
14. Oral Cavity Rt. deep tongue [REDACTED]
15. Oral Cavity: Margin mandibulectomy & floor of mouth resection
16. Neck: Level 1 left neck
17. Neck: Level II left neck
18. Neck: Level III left neck
19. Neck: Level IV neck
20. Neck: Level V left neck

Diagnosis

1. Left inferior alveolus:
- Negative for malignancy.
2. Soft tissue; level VB:
- Adipose tissue, negative for malignancy.
3. Deep paraspinal muscles:
- Positive for squamous cell carcinoma.
4. Anterior scalene muscle:

[page 2 of 7]
- Squamous cell carcinoma invading soft tissues and involving the soft tissue margins.

5. Deep scalene margin:

- Negative for malignancy.

6. Deep scalene margin:

- Negative for malignancy.

7. Carotid margin:

- Negative for malignancy.

8. Right neck; level I:

- Submandibular gland with no pathological abnormalities.

- Six lymph nodes, negative for malignancy (0/6).

9. Left ventral tongue:

- Negative for malignancy.

10. Right ventral tongue:

- Negative for malignancy.

11. Right posterior floor of mouth:

- Negative for malignancy.

12. Posterior floor of mouth:

- Negative for malignancy.

13. Left deep tongue:

- Negative for malignancy.

14. Right deep tongue:

- Negative for malignancy.

15. Oral cavity resection; marginal mandibulectomy and floor of mouth:

- Squamous cell carcinoma, moderately differentiated.

a. The tumour is present in the floor of the mouth.

b. Maximum tumour size is 1.2 cm.

c. Maximum tumour thickness is 1.2 cm.

d. Tumour is close (0.4 cm) to deep margin.

e. All other resection margins are free of tumour (> 0.5 cm).

f. No perineural invasion identified.

g. Bone sections are pending decalcification and will be reported as an addendum.

16. Left neck; level I:

- Metastatic squamous cell carcinoma involving one of seven lymph nodes (1/7).

a. The involved node measures 0.9 cm.

b. Extracapsular extension is present.

c. Tumour is present very close (< 0.1 cm) to the soft tissue margin.

- Submandibular gland with severe atrophy and chronic inflammation, negative for tumour.

17. Left neck; level II:

- Eighteen lymph nodes, negative for malignancy (0/18).

18. Left neck; level III:

- Metastatic squamous cell carcinoma involving seven of fifteen lymph nodes (7/15).

a. The largest involved node measures 5.0 cm.

[page 3 of 7]
- b. Extensive extracapsular extension present.
- c. Tumour is present at the soft tissue margins.

19. Neck; level IV:

- Metastatic squamous cell carcinoma involving four of eighteen lymph nodes (4/18).
- a. The largest involved node measures 3.5 cm.
- b. Extensive extracapsular extension present.
- c. Tumour is present at the soft tissue margins.

20. Left neck; level V:

- Metastatic squamous cell carcinoma involving two of twelve lymph nodes (2/12).
- a. The largest involved node measures 0.5 cm.
- b. No extracapsular extension present.

Synoptic Data

Specimen Type:	Resection: Anterior floor of mouth/mandible.
Tumor Site:	Oral Cavity
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 1.2 cm
	Tumor thickness: 1.2 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Absent
Margins:	Margin(s) involved by tumor
	Location(s): Soft tissues of neck.
Pathologic Staging (pTNM):	pTX: Primary tumor of lip or oral cavity cannot be assessed
	pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx
	Number of regional lymph nodes examined: 76
	Number of regional lymph nodes involved: 14
	Extra-capsular extension of nodal tumor: Present
	pMX: Distant metastasis cannot be assessed

verified by:

Electronically

Clinical History

mouth cancer

Gross Description

1. The specimen is labeled with the patient's name and as "left inferior alveolus". It consists of 3 fragment of polypoid aggregating to 0.9 cm, largest 0.4 cm. The specimen is submitted in toto for frozen section.

[page 4 of 7]
1A frozen section control

2. The specimen is labeled with the patient's name and "level 5B fat". It consists of portion of fibroadipose tissue measuring 2 x 0.8 x 0.4cm. No nodes identified. The specimen is submitted in toto.

2A level 5B fat

3. The specimen is labeled with the patient's name and as "deep paraspinal muscles". It consists of 2 fragment of tissue measuring in aggregate 1.8 x 0.9 x 0.2 cm. The specimen is submitted in toto for frozen section.

3A frozen section control

4. The specimen is labeled with the patient's name and as "anterior scalene muscle". It consists of one piece of query fibrous tissue with roughened surface measuring 3.9 x 1.8 x 0.9 cm. On sectioning, the specimen is gray-white and mostly fibrous. The specimen is submitted in toto.

4A-4C scalene muscle

5. The specimen is labeled with the patient's name and as "deep scalene margin". It consists of a fragment of tissue measuring 1.6 x 0.5 x 0.3 cm. The specimen is submitted in toto for frozen section.

5A frozen section control

6. The specimen is labeled with the patient's name and as "deep scalene margin 2 final resection". It consists of a fragment of tissue measuring 1.8 x 1.7 x 0.4 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

7. The specimen is labeled with the patient's name and as "carotid margin". It consists of a fragment of tissue measuring 4 x 0.1 x 0.1 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and "right level 1". It consists of portion of fibroadipose tissue measuring 6.5 x 3.7 x 1.8cm. It includes a grossly unremarkable submandibular gland measuring 4.2 x 3.5 x 1.7 cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1 x 0.4 x 0.4 cm are identified. Representative sections are submitted.

8A submandibular gland

8B multiple nodes

8C multiple nodes

9. The specimen is labeled with the patient's name and as "left ventral tongue". It consists of a fragment of tissue measuring 0.9 x 0.5 x 0.1 cm. The specimen is submitted in toto for frozen section.

9A frozen section control

10. The specimen is labeled with the patient's name and as "right ventral tongue". It consists of a fragment of tissue measuring 0.5 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

10A frozen section control

[page 5 of 7]
11. The specimen is labeled with the patient's name and as "right posterior floor of mouth". It consists of a fragment of tissue measuring 0.5 x 0.3 x 0.2 cm. The specimen is submitted in toto for frozen section.

11A frozen section control

12. The specimen is labeled with the patient's name and as "posterior floor of mouth". It consists of a fragment of tissue measuring 0.9 x 0.3 x 0.1 cm. The specimen is submitted in toto for frozen section.

12A frozen section control

13. The specimen is labeled with the patient's name and as "left deep tongue". It consists of a fragment of tissue measuring 0.7 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

13A frozen section control

14. The specimen is labeled with the patient's name and as "right deep tongue". It consists of a fragment of tissue measuring 0.5 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

14A frozen section control

15. The specimen is labeled with the patient's name and as margin mandibulectomy and floor of mouth resection. It consists of an anterior mandible with floor of mouth measuring 3.5 AP x 2.5 SI x 4.5 ML cm. It includes a portion of mandible with 9 teeth. There is a tumor arising in anterior floor of mouth. The tumor measures 0.7 AP x 1.2 SI x 0.8 ML cm. The tumor is solid and homogeneous. There is no definitive involvement of bone by the tumour. The tumor is located at 0.5 cm from the closest left floor of mouth margin. Remaining margins are as follows: 0.6 cm from the posterior floor mouth margin, 2 cm from the right floor of mouth margin, 1.8 cm from the inferior muscle resection margin. Representative sections are submitted.

15A left floor of mouth margin

15B right floor of mouth margin

15C posterior floor of mouth margin

15D inferior deep muscle margin

15E-15F tumor

15G left mandible bone margin

15H right mandible bone margin

15I thigh inferior marginal bone margin

15J tumor/mandible bone

16. The specimen is labeled with the patient's name and "level 1 left neck". It consists of portion of fibroadipose tissue measuring 4.6 x 4.6 x 2.6 cm. It includes a submandibular gland measuring 4.2 x 3.8 x 2.2 cm. On sectioning the submandibular gland has a partly fibrous appearance. Multiple lymph nodes ranging from 0.3 x 0.3 x 0.3 to 1.2 x 0.9 x 0.8 cm are identified.

Representative sections are submitted.

16A-16B submandibular gland

16C-16D multiple nodes

16E one node bisected

17. The specimen is labeled with the patient's name and "level 2 left neck". It consists of portion of fibroadipose tissue measuring 5.6 x 4.4 x 3.5 cm. Multiple lymph nodes ranging from 0.1 x 0.1 x 0.1 to 1.5 x 1 x 0.7 cm are identified. Representative sections are submitted.

17A-17D multiple nodes

17E one node bisected

17F one node bisected

[page 6 of 7]
18. The specimen is labeled with the patient's name and "level 3 left neck". It consists of portion of fibroadipose tissue measuring 6.2 x 4.5 x 3.2cm. It is painted with silver nitrate. An exposed partly friable solid tumor on the surface measures 5 x 2 x 2.9 cm. The tumor invades a node and pushes towards the skeletal muscle. The muscle measures 4.5 x 3.8 x 2.6 cm . Multiple lymph nodes ranging from 0.2 to 1 cm are identified. Representative sections are submitted.

18A-18C tumor

18D 2 nodes bisected

18E multiple nodes bisected

18F one node bisected

18G-18H tumor

19. The specimen is labeled with the patient's name and "level 4 neck". It consists of portion of fibroadipose tissue measuring 6.5 x 4.5 x 3.5cm. It is painted with silver nitrate. An exposed white solid partly friable tumor measures 3.5 x 2.5 x 2 cm. The tumor extends towards skeletal muscle. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1 x 0.7 x 0.4 cm are identified.

Representative sections are submitted.

19A-19C tumor

19D-19E multiple nodes

19F one node bisected

19G multiple nodes

19H multiple nodes

19I multiple nodes bisected

20. The specimen is labeled with the patient's name and "level 5 left neck". It consists of portion of fibroadipose tissue measuring 14 x 4 x 2cm. Multiple lymph nodes ranging from 0.2 x 0.2 x 0.2 to 1.5 x 0.6 x 0.6 cm are identified. Representative sections are submitted.

20A-20B multiple nodes

20C one node bisected

20D one node bisected

Quick Section Diagnosis

1. Left inferior alveolus: [REDACTED] Negative for malignancy.

Case reported: [REDACTED]

3. Deep paraspinal muscles [REDACTED] Positive for squamous carcinoma

Case reported [REDACTED]

5. Deep scalene muscle [REDACTED] Negative for malignancy.

Case reported [REDACTED]

[page 7 of 7]
6. Deep scale margin, final resection [REDACTED] Negative for malignancy.

7. Carotid margin [REDACTED] Negative for malignancy.

Case reported: [REDACTED]

9. Left ventral tongue [REDACTED] Negative for malignancy.

10. Right ventral tongue [REDACTED] Negative for malignancy.

11. Right posterior floor of mouth [REDACTED] Negative for malignancy.

12. Left posterior floor of mouth [REDACTED] Negative for malignancy.

13. Left deep tongue [REDACTED] Negative for malignancy.

14. Right deep tongue [REDACTED] Negative for malignancy.

Case reported [REDACTED]

[REDACTED]

Addendum

Out

[REDACTED]

[REDACTED]

Status: Signed

Date Reported:

Addendum Comment

17. Level II left neck: One lymph node showed a focus of granuloma formation. A GMS and ZN stain have been performed and there is no evidence of infectious organisms identified.

Addendum

Out

[REDACTED]

Status: Signed

Date Reported:

Addendum Comment

15. Marginal mandibulectomy/floor of mouth resection (bone sections):
- There is no evidence of bone or bone margin involvement by tumour.

Source: NCI Genomic Data Commons file 4d7d44e0-b112-4216-9568-3d7b4e99c6fe (TCGA-CQ-6228.06A78918-7CF2-4507-B1FB-2382BB928BC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).